Somatic mutation profile of tumor specimen 0DTTXD from CCDI case PBCJRD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.3 years (1,208 days).
Specimen 0DTTXD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e933703d-b938-40cb-9993-34aac9168861.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTTX8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f96cea97-35dd-45b7-b16a-5892a67d6540

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPR158 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs557143314, COSV66271826, COSV66282257; called by muse, varscan2
- SHROOM4 | c.3986G>A p.R1329Q | Missense Mutation (SNP) | VAF 272/333 reads (82%) | SIFT tolerated (0.49); PolyPhen benign (0.36); catalogued as COSV56799460; called by muse, varscan2
- CHADL | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, varscan2
- HMG20B | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MROH6 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, varscan2
- MUC16 | c.17723G>T p.R5908I | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); called by muse, varscan2
- SCRN1 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 120/554 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, varscan2
- SNX25 | c.1691G>A p.S564N | Missense Mutation (SNP) | VAF 266/586 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.619); called by muse, varscan2
- DOCK8 | c.6111A>T p.A2037= | Silent (SNP) | VAF 304/764 reads (40%) | called by muse, varscan2
